Somatic mutation profile of tumor specimen C3L-09098-01 (aliquot CPT0515300006) from CPTAC case C3L-09098, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 71.0 years (25,949 days).
Specimen C3L-09098-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5151bc5-5dfb-4876-9346-612caf3a83fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09098-31 (Blood Derived Normal), aliquot CPT0515330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46ed765d-383f-48a3-b65a-dd74ad7af02b

The open-access MAF lists 190 somatic variants for this specimen: 145 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 39, Nonsense Mutation 9, Splice Site 5, Intron 4, In Frame Del 4, Frame Shift Ins 2, Frame Shift Del 2, In Frame Ins 1, Translation Start Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPT1 | c.160A>T p.K54* (on ENST00000433473; = p.K55* on NM_000310.4) | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as rs386833633, CM950974, COSV65655463; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 115/290 reads (40%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AC139530.2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 203/623 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1443555575; called by muse, mutect2, varscan2
- AJM1 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 293/1265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1378387024; called by muse, mutect2, varscan2
- ANK3 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55078987; called by muse, varscan2
- ARHGAP30 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 66/550 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1433126580; called by muse, mutect2, varscan2
- ARHGAP44 | c.1507T>G p.F503V | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99311695; called by muse, mutect2, varscan2
- ASXL2 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1370921249; called by muse, mutect2, varscan2
- ATP10D | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 43/169 reads (25%) | catalogued as rs74552892, COSV56713422; called by muse, mutect2, varscan2
- B3GALT4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 92/459 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs1377534989; called by muse, mutect2, varscan2
- BOP1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 151/1186 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1462472072; called by muse, mutect2, varscan2
- CACNA1H | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs777503810, COSV61996406; ClinVar: uncertain significance; called by muse, mutect2
- CATSPERD | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs371791746; called by muse, mutect2, varscan2
- CDR2L | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 90/553 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs761841230; called by muse, mutect2, varscan2
- CHSY3 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370639793; called by muse, mutect2, varscan2
- CLEC12A | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58560954, COSV58561308; called by muse, varscan2
- CLK2 | c.802C>T p.R268C (on ENST00000368361 / NM_001294339.2; = p.R267C on NM_003993.4) | Missense Mutation (SNP) | VAF 83/475 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773477474, COSV56944539; called by muse, mutect2, varscan2
- CSRNP1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 105/515 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs142952358, COSV56187375; called by muse, mutect2, varscan2
- CYP2D6 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764892620; called by muse, mutect2, varscan2
- DCC | c.2923G>A p.G975R | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59138445; called by muse, mutect2, varscan2
- DNAH17 | c.4536G>T p.Q1512H | Missense Mutation (SNP) | VAF 87/500 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV67753528; called by muse, mutect2, varscan2
- DPP10 | c.158T>G p.V53G | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100058371; called by muse, mutect2, varscan2
- DUOX2 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 115/908 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs751456977, CD160789; called by muse, mutect2, varscan2
- DZIP1 | c.2065G>A p.D689N (on ENST00000347108; = p.D670N on NM_014934.5) | Missense Mutation (SNP) | VAF 235/391 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as rs776868438, COSV61264846; called by muse, mutect2, varscan2
- HELZ2 | c.5878G>A p.E1960K (on ENST00000467148 / NM_001037335.2; = p.E1391K on NM_033405.3) | Missense Mutation (SNP) | VAF 79/1270 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1296224480; called by muse, mutect2
- INF2 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 208/702 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs757804349; called by muse, mutect2, varscan2
- ITGB1BP2 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV52140603; called by muse, mutect2, varscan2
- ITPR2 | c.2076A>C p.E692D | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs760153936, COSV67270863; called by muse, mutect2, varscan2
- KLK13 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 132/287 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs142773664; called by muse, mutect2, varscan2
- KREMEN2 | c.1316G>T p.G439V (on ENST00000303746 / NM_172229.3; = p.V413F on NM_024507.4) | Missense Mutation (SNP) | VAF 100/541 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.642); catalogued as rs1381065430; called by muse, mutect2, varscan2
- LMOD3 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 93/506 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749726841, COSV101341961; called by muse, mutect2, varscan2
- MCF2L2 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781428915, COSV100192550; called by muse, mutect2, varscan2
- MS4A14 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1301569942; called by muse, mutect2, varscan2
- MYCBP2 | c.6475G>A p.A2159T (on ENST00000357337; = p.A2197T on NM_015057.5) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV62009771; called by muse, mutect2, varscan2
- MYH7B | c.4537C>T p.R1513W | Missense Mutation (SNP) | VAF 373/816 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs762002233, COSV52679170; called by muse, mutect2, varscan2
- NPSR1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100706958; called by muse, mutect2, varscan2
- OR2T12 | c.668T>G p.V223G | Missense Mutation (SNP) | VAF 83/688 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58777346, COSV58779751; called by muse, mutect2, varscan2
- OR4D10 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 153/366 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778016848; called by muse, mutect2, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- PCDH11X | c.2397G>C p.E799D | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.05); catalogued as COSV53439542; called by muse, mutect2, varscan2
- PDE3A | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 103/487 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs994331169; called by muse, varscan2
- PENK | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 86/467 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs149421409; called by muse, mutect2, varscan2
- PRAMEF12 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs375662448; called by muse, mutect2, varscan2
- PREX2 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs751789846, COSV55749122; called by muse, mutect2, varscan2
- RFC1 | c.3220C>T p.P1074S (on ENST00000381897 / NM_001363496.2; = p.P1073S on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV56461644, COSV56465924; called by muse, mutect2, varscan2
- SCN9A | c.349A>T p.R117* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs1553496641; called by muse, mutect2, varscan2
- SEPHS2 | c.1282C>G p.R428G | Missense Mutation (SNP) | VAF 89/528 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as COSV72100813; called by muse, mutect2, varscan2
- SETBP1 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs776221622; called by mutect2, varscan2
- SLITRK6 | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV68389920; called by muse, mutect2, varscan2
- SNX30 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 26/114 reads (23%) | catalogued as COSV65292895; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 48/96 reads (50%) | PolyPhen benign (0.012); catalogued as rs142835503, COSV60322562; called by muse, mutect2, varscan2
- SYT4 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 51/269 reads (19%) | catalogued as COSV54900669; called by muse, mutect2, varscan2
- TAF4 | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 74/604 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs141646555; called by muse, mutect2, varscan2
- TAS1R3 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 118/657 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149300188; called by muse, varscan2
- TLL1 | c.1565T>G p.V522G | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV50325946; called by muse, mutect2, varscan2
- TRAM2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 139/321 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV51732592; called by muse, mutect2, varscan2
- TRIL | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 123/1073 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1167221511; called by muse, mutect2, varscan2
- TTN | c.78493C>T p.R26165* (on ENST00000591111; = p.R18741* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as rs886055237, COSV60165421; called by muse, mutect2, varscan2
- TYR | c.961T>C p.C321R | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs938515275; called by muse, mutect2, varscan2
- UBE3C | c.383_386del p.F128Sfs*16 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs776968248; called by mutect2, pindel, varscan2
- UGT1A10 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.04); catalogued as COSV60854388; called by muse, mutect2, varscan2
- WT1 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 79/437 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as rs779451877, COSV100186471, COSV60078677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFP82 | c.495T>G p.F165L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as rs1055932667; called by muse, mutect2, varscan2
- ZNF157 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.3); catalogued as rs201327488, COSV65659808; called by muse, mutect2, varscan2
- ZNF71 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 225/474 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.337); catalogued as COSV60150865; called by muse, mutect2, varscan2
- ZNF730 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as rs762514346; called by muse, mutect2, varscan2
- ZNF804A | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs762102799, COSV56459328; called by muse, mutect2, varscan2
- A2ML1 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- AC011005.1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ADCY8 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- AMOTL2 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 128/588 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD24 | c.172A>G p.N58D | Missense Mutation (SNP) | VAF 160/513 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ANKRD44 | c.2759A>G p.K920R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ANPEP | c.1629G>T p.W543C | Missense Mutation (SNP) | VAF 402/844 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL2 | c.131_136del p.I44_P46delinsT | In Frame Del (DEL) | VAF 92/304 reads (30%) | called by mutect2, pindel, varscan2
- ATXN7 | c.2154_2155insGCC p.S718_S719insA | In Frame Ins (INS) | VAF 68/431 reads (16%) | called by mutect2, pindel, varscan2
- AXIN2 | c.772A>C p.T258P | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- BRS3 | c.440A>T p.K147M | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC17 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 139/699 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD300A | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 86/386 reads (22%) | called by mutect2, varscan2
- CEP250 | c.5198A>G p.D1733G | Missense Mutation (SNP) | VAF 58/652 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CEP72 | c.1346A>T p.Q449L | Missense Mutation (SNP) | VAF 101/337 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CEP85 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 44/168 reads (26%) | called by muse, mutect2, varscan2
- CHM | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); called by muse, varscan2
- COL4A4 | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CPT1C | c.1415G>T p.W472L | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CSNKA2IP | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DDX53 | c.1027A>C p.S343R | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNHD1 | c.4391_4417del p.Q1464_A1472del | In Frame Del (DEL) | VAF 78/584 reads (13%) | called by mutect2, pindel, varscan2
- DOCK6 | c.4351_4374del p.L1451_L1458del | In Frame Del (DEL) | VAF 74/322 reads (23%) | called by mutect2, varscan2
- DVL1 | c.1771G>C p.E591Q (on ENST00000378888 / NM_001330311.2; = p.E566Q on NM_004421.3) | Missense Mutation (SNP) | VAF 111/670 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- EHF | c.611C>A p.P204Q | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- EMILIN3 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 49/1028 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- EMSY | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT3 | c.10883A>C p.Q3628P | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- FURIN | c.2287C>G p.P763A | Missense Mutation (SNP) | VAF 74/562 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FUT9 | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR153 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 90/529 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID1 | c.2431T>G p.C811G | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HDAC2 | c.1121T>G p.L374* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.689A>C p.E230A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- KRT86 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LRP1 | c.9306C>G p.S3102R | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRP1B | c.7099G>A p.G2367R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGOHB | c.294C>A p.H98Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MAP4K4 | c.1837C>T p.P613S (on ENST00000347699 / NM_001242559.2; = p.P582S on NM_145686.3) | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- MED15 | c.209-1G>A p.X70_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2
- MUC16 | c.37138A>C p.I12380L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 116/744 reads (16%) | SIFT tolerated (0.6); called by muse, mutect2, varscan2
- MYCN | c.781A>C p.S261R | Missense Mutation (SNP) | VAF 65/381 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MYO3B | c.3973C>T p.H1325Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO9B | c.4933T>A p.S1645T | Missense Mutation (SNP) | VAF 56/429 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- NIM1K | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOC3L | c.1176T>G p.D392E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOXO1 | c.209T>G p.L70R (on ENST00000397280 / NM_172168.3; = p.L69R on NM_144603.4) | Missense Mutation (SNP) | VAF 130/507 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NRXN1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OCA2 | c.1877G>A p.C626Y | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PCDH15 | c.5489C>A p.P1830H | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); called by mutect2, varscan2
- PDXK | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PIK3CB | c.2429T>A p.L810* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- PRELID3B | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PRKCZ | c.805G>C p.V269L | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PRSS38 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PSMD1 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- PTPRD | c.4664C>A p.A1555E | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB25 | c.485T>A p.V162D | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- RNF43 | c.224T>A p.I75K | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SACS | c.8180dup p.L2727Ffs*16 | Frame Shift Ins (INS) | VAF 24/184 reads (13%) | called by mutect2, pindel, varscan2
- SAE1 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SHMT1 | c.1054+1G>T p.X352_splice | Splice Site (SNP) | VAF 44/197 reads (22%) | called by muse, mutect2, varscan2
- SPDL1 | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SPTA1 | c.1935A>C p.Q645H | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- STOML3 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SYNJ1 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPTE | c.1058T>G p.L353R (on ENST00000618007 / NM_199261.4; = p.L335R on NM_199259.4) | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF4 | c.134A>C p.E45A | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRIM43 | c.449dup p.I151Dfs*10 | Frame Shift Ins (INS) | VAF 43/133 reads (32%) | called by mutect2, pindel, varscan2
- TSPAN32 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TTN | c.26784G>T p.L8928F (on ENST00000591111; = p.L8001F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/151 reads (17%) | PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TTN | c.14168A>C p.D4723A (on ENST00000591111; = p.D3796A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | PolyPhen benign (0.385); called by muse, mutect2, varscan2
- TUBA4A | c.-5_3+6del | Splice Site (DEL) | VAF 67/352 reads (19%) | called by mutect2, pindel, varscan2
- TULP1 | c.222_233del p.S75_P78del | In Frame Del (DEL) | VAF 70/521 reads (13%) | called by mutect2, pindel, varscan2
- VGF | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 137/767 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ZNF629 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 219/857 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF638 | c.2588-1G>T p.X863_splice | Splice Site (SNP) | VAF 26/43 reads (60%) | called by muse, mutect2, varscan2
- ADGRE3 | c.1410C>T p.V470= | Silent (SNP) | VAF 124/331 reads (37%) | catalogued as rs201863044, COSV53728897; called by muse, mutect2, varscan2
- AFF2 | c.297G>A p.K99= | Silent (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.330G>A p.E110= | Silent (SNP) | VAF 45/247 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.109T>C p.L37= | Silent (SNP) | VAF 124/413 reads (30%) | called by muse, mutect2, varscan2
- ASXL1 | c.6G>A p.K2= | Silent (SNP) | VAF 68/662 reads (10%) | catalogued as rs1192589790; called by muse, mutect2
- C2orf16 | c.1455C>T p.V485= | Silent (SNP) | VAF 106/168 reads (63%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.315C>G p.A105= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- DBX1 | c.285G>A p.P95= | Silent (SNP) | VAF 176/572 reads (31%) | called by muse, mutect2, varscan2
- ECEL1 | c.705G>A p.A235= | Silent (SNP) | VAF 143/524 reads (27%) | catalogued as rs1467200971; called by muse, mutect2, varscan2
- FAM47C | c.2184G>A p.P728= | Silent (SNP) | VAF 82/364 reads (23%) | catalogued as rs149639130, COSV63726592; called by mutect2, varscan2
- FAP | c.1749A>G p.K583= | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as rs369574236; called by muse, mutect2, varscan2
- FAT1 | c.4626A>G p.K1542= | Silent (SNP) | VAF 58/203 reads (29%) | called by muse, mutect2, varscan2
- FAT4 | c.8028T>C p.F2676= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- FCRL1 | c.754A>C p.R252= | Silent (SNP) | VAF 81/277 reads (29%) | called by muse, mutect2, varscan2
- FGL2 | c.195T>A p.T65= | Silent (SNP) | VAF 77/437 reads (18%) | called by muse, mutect2, varscan2
- FN1 | c.888G>A p.P296= | Silent (SNP) | VAF 63/333 reads (19%) | catalogued as rs201079072, COSV60546128; called by muse, mutect2, varscan2
- FNDC3B | c.2325T>A p.I775= | Silent (SNP) | VAF 51/134 reads (38%) | called by muse, mutect2, varscan2
- FOXH1 | c.708A>G p.G236= | Silent (SNP) | VAF 103/716 reads (14%) | called by mutect2, varscan2
- GPR149 | c.708T>G p.A236= | Silent (SNP) | VAF 75/409 reads (18%) | catalogued as rs1235123337; called by muse, mutect2, varscan2
- HELZ2 | c.3039G>A p.T1013= (on ENST00000467148 / NM_001037335.2; = p.T444= on NM_033405.3) | Silent (SNP) | VAF 114/1230 reads (9%) | catalogued as rs776474611; called by muse, mutect2
- IGKV3D-11 | c.96T>G p.S32= | Silent (SNP) | VAF 64/392 reads (16%) | called by muse, mutect2, varscan2
- LRRC45 | c.318G>A p.L106= | Silent (SNP) | VAF 208/488 reads (43%) | catalogued as rs1461207431; called by muse, mutect2, varscan2
- OR4C13 | c.831T>G p.T277= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs1555015914, COSV73648879; called by muse, mutect2, varscan2
- OXLD1 | c.21C>T p.V7= | Silent (SNP) | VAF 295/684 reads (43%) | catalogued as rs552693475, COSV61302850; called by muse, mutect2, varscan2
- PDZD2 | c.8346G>T p.V2782= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- PKP4 | c.255G>A p.E85= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- RAMP3 | c.315C>T p.T105= | Silent (SNP) | VAF 191/616 reads (31%) | catalogued as rs1043997154; called by muse, mutect2, varscan2
- SDS | c.69C>T p.A23= | Silent (SNP) | VAF 94/482 reads (20%) | catalogued as rs368596857, COSV57452915; called by muse, mutect2, varscan2
- SKI | c.345G>A p.V115= | Silent (SNP) | VAF 107/656 reads (16%) | called by muse, mutect2, varscan2
- SLC22A7 | c.1578C>T p.D526= (on ENST00000372585 / NM_153320.2; = p.D524= on NM_006672.3) | Silent (SNP) | VAF 39/492 reads (8%) | catalogued as rs373161942; called by muse, mutect2
- SLC52A3 | c.528A>G p.V176= | Silent (SNP) | VAF 68/459 reads (15%) | called by muse, mutect2, varscan2
- SPOCK3 | c.237C>T p.F79= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs768520189, COSV62717229, COSV62733609; called by muse, mutect2, varscan2
- TLR4 | c.583T>C p.L195= (on ENST00000355622 / NM_138554.5; = p.L155= on NM_003266.4) | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100790653, COSV100790676, COSV62922341; called by muse, mutect2, varscan2
- TLR4 | c.1492T>C p.L498= (on ENST00000355622 / NM_138554.5; = p.L458= on NM_003266.4) | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV62923526; called by muse, mutect2, varscan2
- TNXB | c.6699C>A p.I2233= (on ENST00000647633; = p.I1986= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 111/679 reads (16%) | called by muse, mutect2, varscan2
- UPK3A | c.696C>T p.L232= | Silent (SNP) | VAF 61/248 reads (25%) | catalogued as COSV99343105; called by muse, mutect2, varscan2
- ZFAND2A | c.69A>C p.V23= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- ZNF282 | c.1395G>A p.P465= | Silent (SNP) | VAF 191/349 reads (55%) | catalogued as rs759545294; called by muse, mutect2, varscan2
- ZNF407 | c.3561T>G p.T1187= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- DIP2A | c.2637+17G>A | Intron (SNP) | VAF 72/238 reads (30%) | catalogued as rs768627699; ClinVar: likely benign; called by muse, mutect2, varscan2
- GCAT | c.197-36T>G | Intron (SNP) | VAF 72/376 reads (19%) | called by muse, mutect2, varscan2
- GRIA1 | c.2385+743G>T | Intron (SNP) | VAF 12/65 reads (18%) | called by muse, varscan2
- OR5R1 | chr11:56413639 G>A | 3'Flank (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- PYM1 | c.37+355A>G | Intron (SNP) | VAF 17/289 reads (6%) | called by muse, mutect2
- TP53TG3D | c.*433A>C | 3'UTR (SNP) | VAF 37/114 reads (32%) | catalogued as rs1221178079; called by muse, mutect2, varscan2
